Somatic mutation profile of tumor specimen TCGA-4V-A9QR-01A (aliquot TCGA-4V-A9QR-01A-11D-A423-09) from TCGA case TCGA-4V-A9QR, project TCGA-THYM (Thymoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Thymoma, type B3, malignant; Tissue or organ of origin: Thymus; Age at diagnosis: 51.3 years (18,723 days).
Specimen TCGA-4V-A9QR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e112a155-4a7f-4d44-8128-b1e88c939e57.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-4V-A9QR-10A (Blood Derived Normal), aliquot TCGA-4V-A9QR-10A-01D-A426-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d773c6f7-68b6-44f6-ba3c-2ce3b2fb1a75

The open-access MAF lists 23 somatic variants for this specimen: 17 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 5, Frame Shift Del 2, Translation Start Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HSPA14 | c.1081A>G p.I361V | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.112); catalogued as rs1368442928; called by muse, mutect2, varscan2
- NLRP5 | c.3151G>A p.A1051T | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.087); catalogued as rs374153940; called by muse, mutect2, varscan2
- POSTN | c.2291G>A p.R764K | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.338); catalogued as rs561691739; called by muse, mutect2, varscan2
- SHANK2 | c.3220G>A p.V1074I | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.379); catalogued as rs782391344, COSV99571533; called by muse, mutect2
- TPST2 | c.572C>A p.S191Y | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100114067; called by muse, varscan2
- BCLAF3 | c.1220G>C p.R407T | Missense Mutation (SNP) | VAF 25/147 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- CLIP3 | c.614C>A p.A205D | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- ENTPD2 | c.611del p.G204Vfs*171 | Frame Shift Del (DEL) | VAF 4/36 reads (11%) | called by pindel, varscan2
- MAN2B1 | c.1292G>T p.G431V | Missense Mutation (SNP) | VAF 10/160 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.314); called by muse, mutect2
- PRPF3 | c.459_466del p.I153Mfs*9 | Frame Shift Del (DEL) | VAF 10/97 reads (10%) | called by mutect2, pindel
- PSMA5 | c.106A>G p.T36A | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- RAB3GAP2 | c.1507A>G p.K503E | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.399); called by muse, mutect2
- SLC25A11 | c.71A>G p.K24R | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- SLF2 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 5/41 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- TRPM5 | c.989T>C p.I330T | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- U2SURP | c.2803C>T p.P935S | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- UBE3B | c.2417G>T p.G806V | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CYP2C18 | c.111G>A p.P37= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as rs1564635714, COSV53670398; called by muse, mutect2, varscan2
- FBF1 | c.3022C>A p.R1008= (on ENST00000586717; = p.R1023= on NM_001319193.1) | Silent (SNP) | VAF 7/37 reads (19%) | called by muse, mutect2, varscan2
- HTR7 | c.1011C>T p.T337= | Silent (SNP) | VAF 6/62 reads (10%) | catalogued as rs766954664, COSV53284238; called by mutect2, varscan2
- SPOCK3 | c.69C>A p.A23= | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as rs761642444; called by muse, varscan2
- TIMM22 | c.150C>T p.I50= | Silent (SNP) | VAF 4/24 reads (17%) | called by muse, mutect2, varscan2
- OSGIN1 | n.500G>T | RNA (SNP) | VAF 22/213 reads (10%) | catalogued as COSV100652462; called by muse, mutect2, varscan2
